CCDI case PBCCZB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/c31c678c-b838-4e97-822a-bd9cbc5e1acb

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 13.0 years (4,744 days).

Biospecimens (3 samples)
- Sample 0DPMQP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPMRP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ7WK: Tissue type: Tumor; Specimen type: Solid Tissue.
